Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9R3, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9R3-01A (Primary Tumor).

[page 1 of 2]
Reporting pathologist(s):

CONSULTANT.

Sample

(TYPE UNSPECIFIED) Collected

Received

HISTOLOGY

HISTOLOGY

SPECIMEN

A. Bladder tumour.

B. Base of tumour.

CLINICAL DETAILS

New invasive tumour - TUR.

MACROSCOPY

A. 5 g of firm tissue chippings.

B. 2 pieces of tissue the larger measuring 12 mm.

MICROSCOPY

A.

Grade:

3 poorly differentiated with focal nested pattern.

Growth pattern:

Mixed papillary and solid.

Type:

Transitional cell carcinoma.

Muscularis propria present:

Present.

Stromal invasion:

Invasion of muscularis propria (pT2).

Vascular channel invasion:

Not identified.

Background urothelium:

Flat urothelium is present which is not dysplastic.

SUMMARY

Bladder; Transitional cell carcinoma G3 pT2.

B.

ICD O-3
C67.9
Carcinoma, urothelial NOS 8120/3
path
Carcinoma, transitional cell NOS 8120/3
Site. Bladder NOS C67.9
JW 5/2/14

[page 2 of 2]
Two fragments of muscularis propria both of which are extensively infiltrated by high grade urothelial carcinoma.

SUMMARY

Base of tumour; Extensive infiltration by urothelial carcinoma.

Criteria	11/10/14	Yes	No
Dual/Synchronous Primary	Noted		✓

Source: NCI Genomic Data Commons file f8d651f7-b63a-4401-a492-54ae23edf066 (TCGA-ZF-A9R3.1B5918AB-3C48-405C-BE7F-348E3907060C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).